TCGA case TCGA-RN-AAAQ — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nerve Sheath Tumors; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: St. Joseph's Hospital AZ. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/de509aa1-6f20-480f-bf9d-d6bc04a7f72c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 52 years; Vital status: Alive.

Diagnoses (3)
1. Malignant peripheral nerve sheath tumor (the primary disease): ICD-O-3 morphology code: 9540/3; ICD-10 code: C49.0; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of head, face, and neck; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of head, face, and neck; Classification of tumor: primary; Age at diagnosis: 52.4 years (19,123 days); Year of diagnosis: 2013; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 3.5; Tumor length measurement: 13; Tumor width measurement: 11.
   Pathology details: Consistent pathology review: Yes; Necrosis percent: 50; Necrosis present: Yes; Tumor depth descriptor: Deep.
2. Recurrence of diagnosis 1 (Malignant peripheral nerve sheath tumor), site: Upper limb, NOS. Age at diagnosis: 53.2 years (19,430 days); Days to diagnosis: 307 days; Prior treatment: Yes.
3. Recurrence of diagnosis 1 (Malignant peripheral nerve sheath tumor), site: Head, face or neck, NOS. Age at diagnosis: 53.2 years (19,430 days); Days to diagnosis: 307 days; Prior treatment: Yes.

Follow-up (5 entries)
- Days to follow up: 190 days; Disease response: Tumor Free.
- Day 307 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Upper limb, NOS; Days to recurrence: 307 days.
- Day 307 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Head, face or neck, NOS; Days to recurrence: 307 days.
- Days to follow up: 340 days; Disease response: With Tumor.
- Days to follow up: 510 days (1.4 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 6.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-RN-AAAQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 660 mg.
  Slide TCGA-RN-AAAQ-01A-02-TS2: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 8; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-RN-AAAQ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-RN-AAAQ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free.
- Primary pathology: Histologic diagnosis: Malignant Peripheral Nerve Sheath Tumors (MPNST); Tumor total necrosis: Extensive Necrosis (>50%); Metastatic disease confirmed: No.
- Primary pathology, Synovial sarcoma: Mpnst nf indicator: NF1; Mpnst nf familial or sporadic: Familial; Mpnst nf1 genetic testing indicator: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Upper Extremity - Shoulder/axilla.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease.
- Follow-up form 2: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Partial Response.
- Drug treatment 1: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 40; Days from index date to pharmaceutical treatment ended: 89; Pharmaceutical therapy drug name: Ifosfamide; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Complete Response.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 2: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 362; Days from index date to pharmaceutical treatment ended: 392; Pharmaceutical therapy drug name: Ifosfamide; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Partial Response.
- Drug treatment 3: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 392; Days from index date to pharmaceutical treatment ended: 453; Pharmaceutical therapy drug name: Adriamycin; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Partial Response.
- Drug treatment 4: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 392; Days from index date to pharmaceutical treatment ended: 453; Pharmaceutical therapy drug name: Ifosfamide; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Partial Response.
- Radiation treatment 1: Days from index date to radiation therapy started: 40; Days from index date to radiation therapy ended: 89; Radiation therapy type: External; Radiation total dose: 6300; Radiation adjuvant units: cGy; Radiation adjuvant fractions total: 35; Radiation therapy site: Primary Tumor Field; Radiation therapy ongoing indicator: No; Treatment best response: Complete Response.
- Radiation treatment 2: Days from index date to radiation therapy started: 362; Days from index date to radiation therapy ended: 392; Radiation therapy type: External; Radiation total dose: 4500; Radiation adjuvant units: cGy; Radiation adjuvant fractions total: 30; Radiation therapy site: Local Recurrence; Radiation therapy ongoing indicator: No; Treatment best response: Partial Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 510 days; disease-specific survival: no event (censored), 510 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 307 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-RN-AAAQ-01A-21D-A38Y-01): tumor purity 0.58, ploidy 3.24, whole-genome doublings 1.
